Somatic mutation profile of tumor specimen MMRF_2498_1_BM_CD138pos (aliquot MMRF_2498_1_BM_CD138pos_T1_KHS5U_L11611) from MMRF case MMRF_2498, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 43.2 years (15,762 days).
Specimen MMRF_2498_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db193d7d-4ba2-4c50-9c0f-7c6e3a0fd908.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2498_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2498_1_PB_Whole_C3_KHS5U_L11612; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca0ef734-1f5d-4aca-b436-4457938e0721

The open-access MAF lists 42 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, 3'UTR 13, Intron 6, Silent 5, RNA 1, 5'UTR 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL27A1 | c.3392C>T p.P1131L | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs773146237; called by muse, mutect2, varscan2
- DMRT2 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 174/568 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.423); catalogued as rs148245031; called by muse, mutect2, varscan2
- IGHV1-69 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs11557988; called by muse, mutect2, varscan2
- NRCAM | c.2536A>G p.M846V (on ENST00000379028 / NM_001371124.1; = p.M830V on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs553748314; called by muse, mutect2, varscan2
- PTPRM | c.3361G>A p.V1121I | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs370532691; called by muse, mutect2, varscan2
- RYR2 | c.13729A>G p.I4577V | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100768239; called by muse, mutect2, varscan2
- STYXL2 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs898398838, COSV54801751; called by muse, mutect2, varscan2
- USP39 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60381931; called by muse, mutect2, varscan2
- ABCD2 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); called by muse, mutect2
- BICRAL | c.2469T>A p.D823E | Missense Mutation (SNP) | VAF 108/264 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- NLGN1 | c.1635T>G p.N545K | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYTL2 | c.2696C>T p.S899F (on ENST00000528231 / NM_001162951.2; = p.S875F on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP39 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- YTHDC2 | c.4105T>C p.F1369L | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HOMER3 | c.990T>C p.A330= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1410425997; called by muse, mutect2, varscan2
- HSPB7 | c.87G>A p.S29= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs756233228, COSV58892814; called by muse, mutect2, varscan2
- IGLL5 | c.141C>T p.S47= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs191888936, COSV73248969, COSV73251302; called by muse, mutect2, varscan2
- TRBV27 | c.55C>T p.L19= | Silent (SNP) | VAF 53/196 reads (27%) | called by muse, mutect2, varscan2
- TTC6 | c.3027C>T p.T1009= | Silent (SNP) | VAF 54/100 reads (54%) | called by muse, mutect2, varscan2
- AC019294.1 | chr15:75775567 C>T | 5'Flank (SNP) | VAF 6/24 reads (25%) | catalogued as rs765121258; called by muse, varscan2
- BEND2 | c.*326T>C | 3'UTR (SNP) | VAF 13/14 reads (93%) | called by muse, mutect2, varscan2
- BORCS7 | c.*1975A>G | 3'UTR (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- BTF3 | c.-149A>C | 5'UTR (SNP) | VAF 37/150 reads (25%) | called by muse, mutect2, varscan2
- C12orf60 | c.*417dup | 3'UTR (INS) | VAF 41/97 reads (42%) | called by mutect2, pindel, varscan2
- CEP95 | c.2218-25T>C | Intron (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- COMMD9 | chr11:36270068 T>G | 3'Flank (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2
- FOXF2 | c.*193G>T | 3'UTR (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- GPSM1 | c.*359C>T | 3'UTR (SNP) | VAF 11/353 reads (3%) | catalogued as rs1044712234; called by muse, mutect2
- HS6ST1P1 | n.1097G>A | RNA (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- IPCEF1 | c.*946G>A | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- MPL | c.1565+113G>A | Intron (SNP) | VAF 62/117 reads (53%) | called by muse, mutect2, varscan2
- MSH4 | c.*238T>C | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- NPTX1 | c.*28G>A | 3'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs373315478; called by muse, varscan2
- NPTXR | c.*1094G>T | 3'UTR (SNP) | VAF 11/289 reads (4%) | called by muse, mutect2
- OTUD1 | c.*1289T>C | 3'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- PIK3R1 | c.*1570T>A | 3'UTR (SNP) | VAF 36/123 reads (29%) | called by muse, mutect2, varscan2
- RGMA | c.*25G>A | 3'UTR (SNP) | VAF 19/73 reads (26%) | catalogued as rs768583626; called by muse, mutect2, varscan2
- SCP2 | c.1549-864_1549-861del | Intron (DEL) | VAF 7/62 reads (11%) | called by pindel, varscan2
- SRSF10 | c.*611A>G | 3'UTR (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- TTC39A | c.1162-1052A>G | Intron (SNP) | VAF 24/49 reads (49%) | called by mutect2, varscan2
- VPS13C | c.1914+89A>G | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- XAB2 | c.1781-31G>A | Intron (SNP) | VAF 16/57 reads (28%) | catalogued as rs1229036282; called by muse, mutect2, varscan2
